Somatic mutation profile of tumor specimen MMRF_2475_1_BM_CD138pos (aliquot MMRF_2475_1_BM_CD138pos_T1_KHS5U_L11599) from MMRF case MMRF_2475, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 47.4 years (17,313 days).
Specimen MMRF_2475_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4eed83a1-74b8-4867-9176-fcd350336671.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2475_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2475_1_PB_Whole_C3_KHS5U_L11600; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08542272-2e9e-41fa-a92a-ed7e2d8ec3cc

The open-access MAF lists 120 somatic variants for this specimen: 51 protein-altering or splice-affecting, 17 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, 3'UTR 26, Silent 17, Intron 13, 5'UTR 5, 3'Flank 4, Nonsense Mutation 4, 5'Flank 2, RNA 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PKHD1 | c.7893del p.W2631* | Frame Shift Del (DEL) | VAF 51/287 reads (18%) | catalogued as rs1057516607; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- AP3B2 | c.1379-2A>G p.X460_splice | Splice Site (SNP) | VAF 130/250 reads (52%) | catalogued as COSV99916634; called by muse, mutect2, varscan2
- CELSR1 | c.1145C>T p.S382L | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs375013480; called by muse, mutect2, varscan2
- COL8A1 | c.1463C>A p.P488Q | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.855); catalogued as COSV53738994; called by muse, mutect2
- CYP2A7 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as rs745829083; called by muse, mutect2
- EPHA10 | c.2026G>A p.V676M | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs779253922; called by muse, mutect2, varscan2
- FAM71E2 | c.289G>A p.G97S | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.046); catalogued as rs752829333; called by muse, mutect2, varscan2
- FGB | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as COSV57419208; called by muse, mutect2, varscan2
- GABRG1 | c.782C>T p.T261I | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs1000210963, COSV54962111; called by muse, mutect2, varscan2
- GPC6 | c.321A>T p.E107D | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.05); catalogued as COSV100989629; called by muse, mutect2, varscan2
- GPR179 | c.5728G>A p.E1910K (on ENST00000621958; = p.E1909K on NM_001004334.4) | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as rs903436438; called by muse, mutect2
- H3C7 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 78/181 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as COSV55099964; called by muse, mutect2, varscan2
- HLA-DPB1 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 21/198 reads (11%) | catalogued as rs780867126, COSV69602500; called by muse, mutect2, varscan2
- HS3ST3A1 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.16); catalogued as rs1212032884, COSV52374763, COSV52379578; called by muse, mutect2
- IGHV2-70 | c.240C>G p.Y80* | Nonsense Mutation (SNP) | VAF 68/178 reads (38%) | catalogued as rs111365811; called by muse, varscan2
- IGHV2-70 | c.103C>G p.Q35E | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs367964005; called by muse, varscan2
- IGHV2-70D | c.161G>C p.R54P | Missense Mutation (SNP) | VAF 77/138 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as rs1303497497; called by muse, varscan2
- IGHV3-33 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 80/296 reads (27%) | catalogued as rs750141531; called by muse, mutect2, varscan2
- KIF26B | c.4934C>T p.T1645M | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1462889450, COSV63639842; called by muse, mutect2
- LEPROTL1 | c.175A>G p.T59A | Missense Mutation (SNP) | VAF 65/403 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs754379568; called by muse, mutect2, varscan2
- LRP2 | c.2812C>T p.R938* | Nonsense Mutation (SNP) | VAF 20/321 reads (6%) | catalogued as COSV55539693; called by muse, mutect2
- MTDH | c.1004A>G p.D335G | Missense Mutation (SNP) | VAF 69/149 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs756654848; called by muse, mutect2, varscan2
- NLRP2 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs200189881; called by muse, mutect2
- PCIF1 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs749402768, COSV65026485; called by muse, mutect2
- RGS19 | c.347A>C p.N116T | Missense Mutation (SNP) | VAF 93/208 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100180845; called by muse, mutect2, varscan2
- SAMD3 | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.642); catalogued as COSV100931880, COSV63714881; called by muse, mutect2, varscan2
- SCLT1 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs748010222; called by muse, mutect2, varscan2
- SPATA6 | c.1386T>G p.F462L | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.919); catalogued as COSV64061633; called by muse, mutect2, varscan2
- XIRP2 | c.3220G>A p.D1074N (on ENST00000628543; = p.D1249N on NM_152381.6) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54685657; called by muse, mutect2
- ZNF285 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 28/360 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as rs765848183, COSV58410103; called by muse, mutect2
- APOBEC3D | c.260T>C p.F87S | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BARHL1 | c.230A>G p.H77R | Missense Mutation (SNP) | VAF 12/251 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.021); called by muse, mutect2
- BRPF1 | c.960C>G p.C320W | Missense Mutation (SNP) | VAF 48/440 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSF1R | c.712C>A p.Q238K | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- FIGNL2 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FZD6 | c.1166G>A p.G389D | Missense Mutation (SNP) | VAF 110/280 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH6 | c.1270A>G p.N424D | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- KCNJ4 | c.805A>C p.S269R | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAM | c.498C>A p.S166R | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2
- MMP3 | c.884C>A p.S295Y | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- MTREX | c.1736T>A p.I579N | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PTPDC1 | c.647C>T p.A216V (on ENST00000375360 / NM_177995.3; = p.A268V on NM_152422.4) | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- RPS18 | c.352C>G p.R118G | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- SLC6A14 | c.590A>G p.N197S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SP1 | c.1801C>T p.R601W (on ENST00000327443 / NM_138473.3; = p.R594W on NM_003109.1) | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TBC1D26 | c.381A>T p.K127N | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.104); called by muse, mutect2
- TRIM28 | c.2386A>G p.M796V | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.113); called by muse, mutect2
- ZNF423 | c.1303A>T p.I435F (on ENST00000563137 / NM_001379286.1; = p.I427F on NM_015069.4) | Missense Mutation (SNP) | VAF 7/204 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- ZNF541 | c.3694G>A p.E1232K | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.443); called by muse, mutect2
- ZNF675 | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- BRINP3 | c.2184T>G p.L728= | Silent (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- CLSTN1 | c.1905C>T p.C635= (on ENST00000377298 / NM_001009566.3; = p.C625= on NM_014944.4) | Silent (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2, varscan2
- CR1L | c.81G>A p.L27= | Silent (SNP) | VAF 15/144 reads (10%) | catalogued as rs746701479; called by muse, mutect2, varscan2
- EXO1 | c.1413G>A p.K471= | Silent (SNP) | VAF 95/231 reads (41%) | called by muse, mutect2, varscan2
- FADD | c.60G>C p.L20= | Silent (SNP) | VAF 70/146 reads (48%) | catalogued as COSV100096786; called by muse, mutect2, varscan2
- IGHJ5 | c.27A>C p.G9= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as rs373584630; called by muse, varscan2
- IGHV2-70 | c.156A>G p.G52= | Silent (SNP) | VAF 74/158 reads (47%) | catalogued as rs1232476476; called by muse, varscan2
- IGLV3-1 | c.153T>A p.A51= | Silent (SNP) | VAF 72/81 reads (89%) | catalogued as rs571682243; called by muse, mutect2, varscan2
- IGLV3-1 | c.294T>C p.A98= | Silent (SNP) | VAF 103/133 reads (77%) | catalogued as rs546240484; called by muse, mutect2, varscan2
- KIF16B | c.1497G>A p.E499= | Silent (SNP) | VAF 20/149 reads (13%) | called by muse, mutect2, varscan2
- PTPN21 | c.1983G>A p.A661= | Silent (SNP) | VAF 30/107 reads (28%) | called by muse, mutect2, varscan2
- RNMT | c.1365C>T p.T455= | Silent (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- SORBS2 | c.2841C>T p.Y947= (on ENST00000284776 / NM_021069.5; = p.Y513= on NM_003603.6) | Silent (SNP) | VAF 91/204 reads (45%) | catalogued as rs773883364; called by muse, mutect2, varscan2
- TACC2 | c.7317G>C p.R2439= (on ENST00000334433; = p.R517= on NM_006997.4) | Silent (SNP) | VAF 27/216 reads (13%) | called by muse, mutect2, varscan2
- TEX14 | c.2622C>T p.A874= (on ENST00000240361 / NM_001201457.2; = p.A868= on NM_031272.5) | Silent (SNP) | VAF 54/111 reads (49%) | called by muse, mutect2, varscan2
- TG | c.5682T>C p.L1894= | Silent (SNP) | VAF 37/90 reads (41%) | called by muse, mutect2, varscan2
- ZC3H11A | c.850C>T p.L284= | Silent (SNP) | VAF 5/91 reads (5%) | called by muse, mutect2
- AC006486.1 | c.23-2982T>A | Intron (SNP) | VAF 19/228 reads (8%) | called by muse, mutect2
- AC012313.8 | n.4889T>A | RNA (SNP) | VAF 4/67 reads (6%) | called by muse, mutect2
- ACY1 | c.94+80T>C | Intron (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- AL035461.3 | c.*2241del | 3'UTR (DEL) | VAF 27/66 reads (41%) | called by mutect2, pindel, varscan2
- BIRC3 | c.-1865A>T | 5'UTR (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
- CDH7 | chr18:65884561 G>T | 3'Flank (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- CDH7 | chr18:65884562 T>A | 3'Flank (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
- CEP126 | c.*1839A>G | 3'UTR (SNP) | VAF 28/60 reads (47%) | called by muse, varscan2
- CEP126 | c.*1859A>C | 3'UTR (SNP) | VAF 28/60 reads (47%) | called by muse, varscan2
- CFAP65 | c.1385-69C>T | Intron (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2
- CLNK | c.*570T>C | 3'UTR (SNP) | VAF 2/13 reads (15%) | called by muse, mutect2
- CNOT9 | c.*543T>G | 3'UTR (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- CUX1 | c.*2608T>C | 3'UTR (SNP) | VAF 84/138 reads (61%) | called by muse, mutect2, varscan2
- DDX3X | c.-59C>A | 5'UTR (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- DLG2 | c.205-65810C>T | Intron (SNP) | VAF 34/231 reads (15%) | catalogued as rs745933356, COSV99712122; called by muse, mutect2, varscan2
- DMD | c.*1586A>C | 3'UTR (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- DTX1 | c.-136G>A | 5'UTR (SNP) | VAF 35/91 reads (38%) | called by muse, mutect2, varscan2
- ERCC4 | c.1102+892A>T | Intron (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- FNBP1L | c.1165-31T>C | Intron (SNP) | VAF 19/65 reads (29%) | called by muse, mutect2, varscan2
- GAB1 | chr4:143336832 G>T | 5'Flank (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- HAVCR1 | c.*28C>T | 3'UTR (SNP) | VAF 248/423 reads (59%) | catalogued as rs1177354352, COSV100208308; called by muse, mutect2, varscan2
- INSC | c.*122T>C | 3'UTR (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2
- KCTD5 | c.*1150G>A | 3'UTR (SNP) | VAF 77/180 reads (43%) | catalogued as rs960329887; called by muse, mutect2, varscan2
- KIF26B | c.999+3264C>T | Intron (SNP) | VAF 9/58 reads (16%) | catalogued as rs1017464123, COSV68572324; called by muse, mutect2, varscan2
- LTBP3 | c.*113G>A | 3'UTR (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- MINPP1 | c.*24C>A | 3'UTR (SNP) | VAF 59/118 reads (50%) | catalogued as rs1490589835; called by muse, mutect2, varscan2
- MIR182 | n.69G>A | RNA (SNP) | VAF 12/99 reads (12%) | called by muse, mutect2
- MOCS1 | c.*475C>T | 3'UTR (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- NEMP2 | c.*1402A>G | 3'UTR (SNP) | VAF 27/52 reads (52%) | called by muse, mutect2, varscan2
- NETO1 | c.29-457C>T | Intron (SNP) | VAF 18/105 reads (17%) | called by muse, mutect2, varscan2
- NUDT1 | chr7:2242246 C>T | 5'Flank (SNP) | VAF 49/75 reads (65%) | called by muse, mutect2, varscan2
- PDGFC | c.*2377G>A | 3'UTR (SNP) | VAF 7/67 reads (10%) | catalogued as rs1035864388; called by muse, mutect2
- PFKFB2 | chr1:207078998 G>A | 3'Flank (SNP) | VAF 15/219 reads (7%) | catalogued as rs144692490; called by muse, mutect2
- PLEKHG3 | c.*480G>A | 3'UTR (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- PRDM1 | c.*1810_*1811del | 3'UTR (DEL) | VAF 8/82 reads (10%) | called by pindel, varscan2
- PSG4 | c.*245G>C | 3'UTR (SNP) | VAF 36/136 reads (26%) | catalogued as COSV54942341; called by muse, mutect2, varscan2
- PSKH1 | c.*1296C>T | 3'UTR (SNP) | VAF 86/190 reads (45%) | catalogued as rs1440585661; called by muse, mutect2, varscan2
- QKI | c.*3910A>T | 3'UTR (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2, varscan2
- REC8 | c.-391C>A | 5'UTR (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- RNF217 | c.1116+2710A>C | Intron (SNP) | VAF 31/210 reads (15%) | called by muse, mutect2, varscan2
- RPL5 | c.528-81G>C | Intron (SNP) | VAF 8/114 reads (7%) | catalogued as COSV59873273; called by muse, mutect2
- SFSWAP | c.2409-1146G>C | Intron (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- SLC35A3 | chr1:100026665 T>C | 3'Flank (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2
- SP7 | c.*1538T>G | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2
- STK38 | c.*378A>G | 3'UTR (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- TBC1D2B | c.1582-38C>G | Intron (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2, varscan2
- TCTN1 | c.-101C>A | 5'UTR (SNP) | VAF 8/151 reads (5%) | called by muse, mutect2
- TFEC | c.*4557G>C | 3'UTR (SNP) | VAF 9/127 reads (7%) | called by muse, mutect2
- TXNRD2 | c.*191C>T | 3'UTR (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- USP25 | c.*356G>A | 3'UTR (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- VPS33A | c.484-1864G>A | Intron (SNP) | VAF 31/160 reads (19%) | called by muse, mutect2, varscan2
- ZFHX4 | c.*1008C>A | 3'UTR (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2
